TCGA case TCGA-AG-A036 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f2a8deb2-0e2c-4bbd-8fa1-99b7abb2f3aa

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 71.7 years (26,206 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 3,562 days (9.8 years).
   Pathology details: Circumferential resection margin: 1; Consistent pathology review: Yes; Lymph nodes positive: 18; Lymph nodes tested: 30.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 92 days; Days to treatment end: 215 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 92 days; Days to treatment end: 215 days; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.

Follow-up (2 entries)
- Days to follow up: 31 days; Disease response: With Tumor.
- Days to follow up: 3,562 days (9.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 2.2 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-A036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 300 mg.
  Slide TCGA-AG-A036-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide TCGA-AG-A036-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 18; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-AG-A036-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AG-A036-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 400 mg.
  Slide TCGA-AG-A036-11A-01-BS1: Section location: Bottom; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 3.
  Slide TCGA-AG-A036-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 2.2; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,562 days; disease-specific survival: no event (censored), 3,562 days; disease-free interval: no event (censored), 3,562 days; progression-free interval: no event (censored), 3,562 days.
